Gene-level copy-number profile of tumor specimen TCGA-SN-A6IS-01A from TCGA case TCGA-SN-A6IS, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 26.3 years (9,618 days).
Specimen TCGA-SN-A6IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.4e78616c-6f35-4243-8ceb-2d7bb3529fbb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SN-A6IS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9f6f508b-174d-47a1-829c-88c65cea753f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 83; copy number 2: 16,259; copy number 3: 33,761; copy number 4: 3,992; copy number 5: 2,517; copy number 6: 2,020; copy number 7: 131; copy number 8: 850; copy number 9: 207.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SN-A6IS-01A-11D-A434-01): tumor purity 0.51, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,188 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–34,249,958, 850 genes, copy number 8 (broad region; genes not listed).
- chr22:20,707,691–25,729,294, 337 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr22:25,756,318–25,756,669, 1 gene, copy number 7: AL022329.3.

Autosomal genes at a single copy (total copy number 1): 83. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
